Somatic mutation profile of tumor specimen MMRF_1880_1_BM_CD138pos (aliquot MMRF_1880_1_BM_CD138pos_T1_KBS5U_L07239) from MMRF case MMRF_1880, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.5 years (24,288 days).
Specimen MMRF_1880_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f8f0693-d86a-4ee0-8c08-703642646bb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1880_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1880_1_PB_Whole_C9_KBS5U_L07222; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61ae854a-f644-4ca0-894e-c43241426c16

The open-access MAF lists 82 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, 3'UTR 18, Silent 9, Intron 9, Frame Shift Del 2, RNA 2, 3'Flank 2, Nonsense Mutation 2, Frame Shift Ins 1, 5'UTR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.2201C>T p.T734I | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs886046207, COSV63978677; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARD10 | c.2971G>A p.A991T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs769913613; called by muse, mutect2, varscan2
- CDK13 | c.4016T>A p.F1339Y | Missense Mutation (SNP) | VAF 73/242 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.931); catalogued as rs1246652640; called by muse, mutect2, varscan2
- CYP4F22 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761963345, COSV54107667; called by muse, mutect2, varscan2
- EPPK1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs782397354, COSV73262380; called by muse, mutect2, varscan2
- GNAT3 | c.239C>A p.S80Y | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1355656169; called by muse, mutect2, varscan2
- IGHD3-9 | c.5T>C p.L2S | Missense Mutation (SNP) | VAF 15/15 reads (100%) | catalogued as rs369734836; called by muse, mutect2, varscan2
- IGHV1-69 | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs782425771; called by muse, mutect2, varscan2
- IGHV2-70 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.701); catalogued as rs376644103; called by muse, varscan2
- IGHV2-70 | c.220T>C p.W74R | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.688); catalogued as rs375052259; called by muse, varscan2
- IGLV3-1 | c.245G>C p.G82A | Missense Mutation (SNP) | VAF 106/173 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs373575867; called by muse, varscan2
- IGLV3-1 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 127/194 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs142180628; called by muse, varscan2
- LCP2 | c.1517G>A p.R506K | Missense Mutation (SNP) | VAF 150/456 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV50469362; called by muse, mutect2, varscan2
- MYO10 | c.2863C>T p.R955W | Missense Mutation (SNP) | VAF 133/209 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs770160016; called by muse, mutect2, varscan2
- PCDHAC2 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs782716187, COSV53842989; called by muse, mutect2
- PPME1 | c.710+1G>A p.X237_splice | Splice Site (SNP) | VAF 16/290 reads (6%) | catalogued as rs1425660127; called by muse, mutect2
- PTPRF | c.4479del p.F1493Lfs*47 | Frame Shift Del (DEL) | VAF 36/89 reads (40%) | catalogued as COSV63448605; called by mutect2, pindel, varscan2
- RBP3 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373982809; ClinVar: uncertain significance; called by muse, mutect2
- RINT1 | c.2090A>G p.N697S | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.714); catalogued as rs777493133; called by muse, mutect2, varscan2
- SI | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as rs201105530, COSV52281341, COSV52303550; called by muse, mutect2, varscan2
- SLC26A4 | c.768G>A p.T256= | Splice Region (SNP) | VAF 8/22 reads (36%) | catalogued as rs552050976, CD1213291; called by muse, varscan2
- ZNF804B | c.2537G>T p.C846F | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.38); catalogued as COSV60814748; called by muse, mutect2
- ADGRA3 | c.2770G>T p.A924S | Missense Mutation (SNP) | VAF 80/156 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- ARHGAP35 | c.2399T>A p.L800H | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B4GALNT1 | c.653G>A p.R218K | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- BICRAL | c.2312T>C p.L771P | Missense Mutation (SNP) | VAF 23/261 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL6A5 | c.2893G>T p.A965S | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CYFIP1 | c.2428A>T p.K810* | Nonsense Mutation (SNP) | VAF 79/369 reads (21%) | called by muse, mutect2, varscan2
- DKC1 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- FAM102A | c.388A>G p.T130A | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); called by muse, mutect2
- FAM160A2 | c.1030G>T p.V344L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- HIVEP3 | c.1989dup p.Y664Ifs*23 | Frame Shift Ins (INS) | VAF 60/167 reads (36%) | called by mutect2, pindel, varscan2
- IGHV2-70D | c.310A>G p.T104A | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by muse, varscan2
- MARK3 | c.1053_1059del p.K351Nfs*150 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | called by mutect2, pindel, varscan2
- MBD4 | c.606A>C p.R202S | Missense Mutation (SNP) | VAF 200/312 reads (64%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYBPH | c.1107A>T p.K369N | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- MYH3 | c.1129G>C p.D377H | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MYH8 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- OR5D18 | c.601T>C p.F201L | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.107); called by muse, mutect2
- TMC1 | c.1208G>A p.W403* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- WDR45 | c.770A>G p.D257G (on ENST00000376372 / NM_001029896.2; = p.D258G on NM_007075.3) | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- GALNT18 | c.561G>A p.K187= | Silent (SNP) | VAF 11/185 reads (6%) | called by muse, mutect2
- NFATC1 | c.1371A>G p.G457= | Silent (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- NTN1 | c.639C>T p.L213= | Silent (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- PDCD7 | c.619C>T p.L207= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1369199154; called by muse, mutect2
- RERE | c.3348G>A p.P1116= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs754887260; called by muse, mutect2, varscan2
- RTL3 | c.1050G>A p.L350= | Silent (SNP) | VAF 7/93 reads (8%) | called by muse, mutect2
- SEMA4G | c.411C>T p.A137= | Silent (SNP) | VAF 87/191 reads (46%) | called by muse, mutect2, varscan2
- SURF6 | c.588C>T p.P196= | Silent (SNP) | VAF 36/173 reads (21%) | catalogued as rs375054880; called by muse, mutect2, varscan2
- SYNPO | c.2436C>T p.R812= (on ENST00000394243 / NM_001166208.2; = p.R568= on NM_007286.6) | Silent (SNP) | VAF 20/294 reads (7%) | called by muse, mutect2
- ALS2CL | c.2685-80G>A | Intron (SNP) | VAF 61/191 reads (32%) | catalogued as rs1453030249; called by muse, mutect2, varscan2
- AMACR | c.-8G>A | 5'UTR (SNP) | VAF 43/111 reads (39%) | called by muse, mutect2, varscan2
- ANTXR2 | c.*5404C>G | 3'UTR (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- BMP6 | c.*499_*533del | 3'UTR (DEL) | VAF 20/216 reads (9%) | called by mutect2, pindel
- C5orf60 | n.529T>C | RNA (SNP) | VAF 5/21 reads (24%) | catalogued as rs867509473; called by mutect2, varscan2
- CDS1 | c.*1789dup | 3'UTR (INS) | VAF 34/92 reads (37%) | catalogued as rs938607405; called by mutect2, varscan2
- CHRNB2 | c.*3866G>A | 3'UTR (SNP) | VAF 12/132 reads (9%) | called by muse, mutect2
- CNTNAP2 | c.*933A>C | 3'UTR (SNP) | VAF 33/93 reads (35%) | called by muse, mutect2, varscan2
- DAPK2 | c.858+2019T>C | Intron (SNP) | VAF 61/220 reads (28%) | called by muse, mutect2, varscan2
- DNAI1 | c.262-1214A>G | Intron (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.46+184G>A | Intron (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2
- FAM172BP | n.141C>A | RNA (SNP) | VAF 9/199 reads (5%) | called by muse, mutect2
- HAPLN1 | c.*2467A>C | 3'UTR (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- HID1 | c.388-61C>T | Intron (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- IDE | c.*2251G>C | 3'UTR (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- ISM2 | c.*875dup | 3'UTR (INS) | VAF 47/118 reads (40%) | called by mutect2, pindel, varscan2
- LTB | c.162+61G>A | Intron (SNP) | VAF 32/72 reads (44%) | catalogued as rs932462715; called by muse, mutect2, varscan2
- MT1F | c.28+29G>T | Intron (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- MTFP1 | c.*18G>A | 3'UTR (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- PDE10A | c.*4399A>G | 3'UTR (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- PHF20L1 | c.*721A>G | 3'UTR (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.*1249C>T | 3'UTR (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2
- PLXNA4 | c.*3569A>G | 3'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2, varscan2
- PNKD | c.*673G>A | 3'UTR (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- RBM46 | c.1403-639G>A | Intron (SNP) | VAF 41/89 reads (46%) | called by muse, mutect2, varscan2
- RRP1 | c.*1061A>G | 3'UTR (SNP) | VAF 39/154 reads (25%) | catalogued as rs754803446; called by muse, mutect2, varscan2
- SNORA15B-1 | chr7:65075087 G>A | 3'Flank (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- STARD4 | c.155+22T>G | Intron (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- TMPRSS11E | c.*689A>G | 3'UTR (SNP) | VAF 58/123 reads (47%) | catalogued as rs1377562056; called by muse, mutect2, varscan2
- TOR1AIP1 | c.*589A>G | 3'UTR (SNP) | VAF 54/112 reads (48%) | called by muse, mutect2, varscan2
- UBL4A | c.*1129C>A | 3'UTR (SNP) | VAF 69/148 reads (47%) | called by muse, mutect2, varscan2
- UTS2B | chr3:191264855 T>A | 3'Flank (SNP) | VAF 35/105 reads (33%) | called by muse, mutect2, varscan2
